Somatic mutation profile of tumor specimen TCGA-24-0980-01A (aliquot TCGA-24-0980-01A-01W-0421-09) from TCGA case TCGA-24-0980, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.6 years (19,579 days).
Specimen TCGA-24-0980-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9739fab9-8ba7-4d6b-a766-5e1892a7f2dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-0980-10A (Blood Derived Normal), aliquot TCGA-24-0980-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd97e261-5622-46bb-9096-ba3c7783dc37

The open-access MAF lists 41 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 30, Silent 8, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD35 | c.818C>G p.P273R | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV62910616, COSV62911200; called by muse, mutect2, varscan2
- ATM | c.7519G>A p.D2507N | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as CD004352, COSV53749401; called by muse, mutect2, varscan2
- AURKC | c.508G>C p.E170Q (on ENST00000302804 / NM_001015878.2; = p.E136Q on NM_003160.3) | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57138892; called by muse, mutect2, varscan2
- CAP1 | c.469A>G p.M157V | Missense Mutation (SNP) | VAF 124/385 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61223633; called by muse, mutect2, varscan2
- CCDC88B | c.3374C>T p.A1125V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV57266557; called by muse, mutect2, varscan2
- CCT8L2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs376606608, COSV63463644, COSV63463760; called by muse, mutect2, varscan2
- CD19 | c.165G>T p.E55D | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV61188796; called by muse, mutect2, varscan2
- CHD5 | c.5323G>A p.E1775K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99313452; called by muse, mutect2, varscan2
- CLEC4F | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.935); catalogued as COSV55479754, COSV55479863; called by muse, mutect2, varscan2
- COL4A5 | c.4396C>T p.R1466C | Missense Mutation (SNP) | VAF 174/829 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746184634, COSV60359944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A6 | c.296T>A p.V99D | Missense Mutation (SNP) | VAF 193/1929 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57868630; called by muse, mutect2, varscan2
- EFL1 | c.128A>G p.N43S | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51606405; called by muse, mutect2, varscan2
- FGD5 | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as rs751117347, COSV53244747; called by muse, mutect2, varscan2
- FRMD7 | c.138A>T p.E46D | Missense Mutation (SNP) | VAF 148/2060 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100048933; called by muse, mutect2
- GPX6 | c.601C>G p.Q201E | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV62657774; called by muse, mutect2
- HDAC11 | c.716A>T p.E239V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV55473557; called by muse, mutect2, varscan2
- KRT73 | c.983A>C p.K328T | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59839721; called by muse, mutect2
- LRFN1 | c.1364A>G p.Q455R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV50451889; called by muse, mutect2, varscan2
- MAP4 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV64241068; called by muse, mutect2, varscan2
- NSD1 | c.5027C>A p.A1676D | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61777608; called by muse, mutect2, varscan2
- PCDHA11 | c.1173C>G p.H391Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs1554163984, COSV56510714, COSV56557593; called by muse, mutect2, varscan2
- PHLDB2 | c.2804G>A p.C935Y (on ENST00000393925 / NM_001134439.2; = p.C892Y on NM_145753.2) | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67312251; called by muse, mutect2, varscan2
- PRRG1 | c.85A>G p.R29G | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV66157850; called by muse, mutect2, varscan2
- RNF213 | c.15332C>T p.P5111L | Missense Mutation (SNP) | VAF 112/182 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs191077627, COSV60399778; called by muse, mutect2, varscan2
- SLC45A3 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as rs773057305, COSV65655042; called by muse, mutect2, varscan2
- TEX13A | c.475T>G p.W159G | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1556177481; called by muse, mutect2
- TMEM97 | c.411G>T p.L137F | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99880660; called by muse, mutect2
- TP53 | c.498dup p.Q167Tfs*14 | Frame Shift Ins (INS) | VAF 39/68 reads (57%) | catalogued as COSV53753495; called by mutect2, pindel, varscan2
- TTN | c.100955A>T p.K33652I (on ENST00000591111; = p.K26228I on NM_003319.4) | Missense Mutation (SNP) | VAF 74/184 reads (40%) | PolyPhen possibly damaging (0.891); catalogued as COSV60117058; called by muse, mutect2, varscan2
- ZNF426 | c.328T>C p.W110R | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53469524; called by muse, mutect2, varscan2
- ZNF454 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as COSV60768801; called by muse, mutect2, varscan2
- MRC1 | c.3244C>T p.R1082* | Nonsense Mutation (SNP) | VAF 85/267 reads (32%) | called by muse, mutect2, varscan2
- SH3PXD2A | c.1584dup p.S529Qfs*15 (on ENST00000369774 / NM_001365079.1; = p.S501Qfs*15 on NM_014631.2) | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- DUS4L-BCAP29 | c.768A>T p.I256= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV50051875; called by muse, mutect2, varscan2
- GBP7 | c.24A>T p.P8= | Silent (SNP) | VAF 95/248 reads (38%) | catalogued as COSV54010131; called by muse, mutect2, varscan2
- OR2A5 | c.303C>A p.T101= | Silent (SNP) | VAF 183/503 reads (36%) | catalogued as rs1563026611, COSV68738820, COSV68738836; called by muse, mutect2, varscan2
- PCDH19 | c.2919C>T p.P973= (on ENST00000373034 / NM_001184880.2; = p.P925= on NM_020766.3) | Silent (SNP) | VAF 321/741 reads (43%) | catalogued as COSV55264759; called by muse, mutect2, varscan2
- RPS6KL1 | c.1581A>G p.E527= | Silent (SNP) | VAF 74/124 reads (60%) | catalogued as COSV53166535; called by muse, mutect2, varscan2
- SEMA5B | c.2265C>T p.C755= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99531621; called by muse, mutect2
- SNTA1 | c.1227G>A p.E409= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99458679; called by muse, mutect2, varscan2
- USP34 | c.6282T>C p.N2094= | Silent (SNP) | VAF 70/186 reads (38%) | catalogued as COSV68402132; called by muse, mutect2, varscan2
